CCDI case PBCNUZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/8ac9cbb8-6710-42c3-bea0-4026778295e1

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neuroendocrine carcinoma, NOS: ICD-O-3 morphology code: 8246/3; Tissue or organ of origin: Appendix; Age at diagnosis: 16.5 years (6,025 days).

Biospecimens (2 samples)
- Sample 0DWBGB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DWBGN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
